TARGET case TARGET-30-PAKADI — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/827d5381-940d-5cbd-a4d1-4db7fe040524

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Age at diagnosis: 4.0 years (1,456 days); Year of diagnosis: 1994; Days to last follow up: 2,325 days (6.4 years); INSS stage: Stage 4.

Biospecimens (2 samples)
- Sample TARGET-30-PAKADI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAKADI-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
